Surgical pathology report (de-identified scan), TCGA case TCGA-77-8146, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-8146-01A (Primary Tumor).

[page 1 of 2]
Collected [REDACTED]

Histopathology Report

HISTORY

Right lower lobe carcinoma. No pre-op histology.

MACROSCOPIC

Four specimens received:

1: The specimen is labelled 'right upper lobe' and comprises a lobe of lung consistent with right upper lobe measuring 150 mm from superior to inferior, 130 mm from anterior to posterior and approximately 40 mm from medial to lateral. A stapled resection margin, 125 mm in length, is present adjacent to the hilum. A number of fleshy dark coloured lymph nodes are present at the hilum. The pleural surface shows extensive anthracosis and there is an area of pleural puckering posterolaterally overlying the posterior segment. Beneath this area of puckering is a pale tumour mass measuring up to 22 mm in greatest diameter. A bronchial origin is not identified. Tumour is well clear of the bronchial and stapled resection margins. [1A, bronchial resection margin; 1B-C, peribronchial lymph nodes; 1D-G, tumour with overlying pleura; 1H, uninvolved lung parenchyma].

2: The specimen is labelled 'right lower lobe nodule' and comprises a portion of grey tissue, 7 x 8 x 5 mm. Transverse slicing reveals a black nodule, 4 mm in diameter. [BIT after bisection, 2A].

3: The specimen is labelled 'lymph node No. 10' and comprises two portions of fleshy lymph node tissue, 17 x 10 x 7 mm and 9 x 6 x 3 mm. The cut surface of the larger fragment shows fleshy black and grey tissue. [BIT, the larger specimen after bisection, 3A].

4: The specimen is labelled 'lymph node No. 11' and comprises two fragments of greyish-black tissue, 10 x 6 x 4 mm and 10 x 7 x 3 mm. [BIT, 4A].

MICROSCOPIC

1: Sections show a poorly differentiated squamous cell carcinoma. Several cavities are present within the tumour and focally there appears to be an in situ component. The lesion is subpleural but pleural invasion is not identified. There is no blood vessel invasion and no lymphatic permeation is seen. No perineural permeation is identified. The lesion is well clear of the bronchial resection margin. No lymph node metastases are seen. Within the lymph nodes, there are numerous non-necrotising sarcoidal granulomata. The adjacent lung shows evidence of mild emphysema.

2: Sections show a silicotic nodule. There is no evidence of malignancy.

3-4: Sections of the lymph nodes show reactive changes only. Numerous non-necrotising sarcoidal granulomata are identified. There is no evidence of

[page 2 of 2]
[REDACTED]

Collected [REDACTED]

Histopathology Report

malignancy.

SUMMARY

1-4: Right upper lobe and lymph nodes:

A: Poorly differentiated squamous cell carcinoma; 22 mm in maximal dimension.

B: No blood vessel, lymphatic or perineural invasion present.

C: No pleural invasion identified; clear of bronchial margin.

D: No lymph node metastases. Sarcoidal granulomata present.

E: T1N0

F: Non-neoplastic lung: Emphysema; right lower lobe silicotic nodule.

COMMENT

The sarcoidal granulomata within the lymph nodes may represent sarcoidosis but are more likely a sarcoidal reaction to the carcinoma.

[REDACTED]

SUPPLEMENTARY REPORT

No pleural invasion is identified with special stains. No microorganisms are identified within the lymph node granulomata with special stains (Grocott and Ziehl-Neelsen).

[REDACTED]

c.c. Lung Cancer Registry

[REDACTED]

Source: NCI Genomic Data Commons file 88929a34-fee9-47b3-9d8c-eaa1bb31d447 (TCGA-77-8146.5D6612D3-0A94-4B7C-9297-A9A5ADA70C65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).